Somatic mutation profile of tumor specimen TCGA-24-1417-01A (aliquot TCGA-24-1417-01A-01W-0549-09) from TCGA case TCGA-24-1417, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IV; Tumor grade: G3; Age at diagnosis: 54.1 years (19,775 days).
Specimen TCGA-24-1417-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 83c6f403-329f-450b-b885-ab58b5e51640.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1417-10A (Blood Derived Normal), aliquot TCGA-24-1417-10A-01W-0549-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e80b65e-c599-4a35-b30a-ec9bf570c8a3

The open-access MAF lists 102 somatic variants for this specimen: 72 protein-altering or splice-affecting, 27 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, Silent 27, Nonsense Mutation 5, Splice Site 4, Frame Shift Del 2, 3'UTR 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 45/85 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912651, CM010465, CM900211, COSV52662035, COSV52797251, COSV53097881; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.2158G>T p.V720F | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV101036866; called by muse, mutect2, varscan2
- ACTG1 | c.697T>A p.S233T | Missense Mutation (SNP) | VAF 11/17 reads (65%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.795); catalogued as COSV59512379; called by muse, mutect2, varscan2
- ADAM15 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55130435; called by muse, mutect2, varscan2
- ADGRE3 | c.882+2T>G p.X294_splice | Splice Site (SNP) | VAF 79/425 reads (19%) | catalogued as COSV53735803; called by muse, mutect2, varscan2
- ALB | c.139G>A p.V47M | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.874); catalogued as rs372694396; called by muse, mutect2, varscan2
- ARCN1 | c.487G>C p.A163P | Missense Mutation (SNP) | VAF 40/191 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV50618312; called by muse, mutect2, varscan2
- ARHGEF2 | c.1198C>T p.R400C (on ENST00000361247 / NM_001162383.2; = p.R372C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/121 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs776511128, COSV58105915; called by muse, mutect2, varscan2
- ARMC2 | c.594T>A p.D198E | Missense Mutation (SNP) | VAF 129/180 reads (72%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV52901752; called by muse, mutect2, varscan2
- ASAP1 | c.784A>T p.K262* | Nonsense Mutation (SNP) | VAF 48/283 reads (17%) | catalogued as COSV63055379; called by muse, mutect2, varscan2
- ASIC5 | c.420T>A p.H140Q | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as COSV72233189; called by muse, mutect2, varscan2
- CBLB | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 48/124 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248842712, COSV51437309; called by muse, mutect2, varscan2
- CBWD1 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1219852361, COSV100070877; called by muse, mutect2, varscan2
- CCKAR | c.1073T>C p.L358P | Missense Mutation (SNP) | VAF 54/88 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99810263; called by muse, mutect2, varscan2
- CDK2 | c.650G>T p.R217L | Missense Mutation (SNP) | VAF 92/313 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV99906718; called by muse, mutect2, varscan2
- CILK1 | c.1095G>T p.Q365H | Missense Mutation (SNP) | VAF 58/165 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.034); catalogued as COSV63156359; called by muse, mutect2, varscan2
- COL1A1 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM033357, COSV99867108; called by muse, mutect2, varscan2
- COL6A3 | c.1229A>T p.D410V | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.265); catalogued as COSV99797941; called by muse, mutect2, varscan2
- DAO | c.862C>G p.Q288E | Missense Mutation (SNP) | VAF 22/232 reads (9%) | SIFT tolerated (0.84); PolyPhen benign (0.001); catalogued as rs1368694476, COSV99948573; called by muse, mutect2
- DENND6A | c.261A>C p.K87N | Missense Mutation (SNP) | VAF 81/126 reads (64%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100231463; called by muse, mutect2, varscan2
- DNTT | c.739C>A p.Q247K | Missense Mutation (SNP) | VAF 21/138 reads (15%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as rs781642778, COSV64523836; called by muse, mutect2, varscan2
- FCRL4 | c.512G>T p.G171V | Missense Mutation (SNP) | VAF 35/192 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV54867158; called by muse, mutect2, varscan2
- FNIP1 | c.1245A>C p.E415D | Missense Mutation (SNP) | VAF 75/211 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.537); catalogued as COSV57201629; called by muse, mutect2, varscan2
- GRIN2A | c.3311C>A p.T1104N | Missense Mutation (SNP) | VAF 61/236 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.03); catalogued as rs755577016, COSV100409241; called by muse, mutect2, varscan2
- H2AC11 | c.8G>T p.G3V | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.954); catalogued as rs749033505, COSV60362989; called by muse, mutect2, varscan2
- IL21R | c.759G>A p.W253* | Nonsense Mutation (SNP) | VAF 36/75 reads (48%) | catalogued as COSV61973019; called by muse, mutect2, varscan2
- ITGAD | c.464T>C p.I155T | Missense Mutation (SNP) | VAF 94/200 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1256691709, COSV66760711; called by muse, varscan2
- KBTBD7 | c.1733G>C p.W578S | Missense Mutation (SNP) | VAF 37/192 reads (19%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.795); catalogued as COSV65267299; called by muse, mutect2, varscan2
- KDM2A | c.2380A>C p.I794L | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58191780; called by muse, mutect2, varscan2
- LIX1 | c.557G>A p.R186Q | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs570322510, COSV57208511; called by muse, mutect2, varscan2
- LIX1L | c.840G>C p.W280C | Missense Mutation (SNP) | VAF 34/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63417234, COSV63417357; called by muse, mutect2, varscan2
- LRP1B | c.13247+1G>T p.X4416_splice | Splice Site (SNP) | VAF 29/74 reads (39%) | catalogued as COSV101256199; called by muse, mutect2, varscan2
- MADD | c.2659G>A p.G887R | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1297053973, COSV60624706, COSV60630448; called by muse, mutect2, varscan2
- MAP4K3 | c.1392G>A p.M464I | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV99810343; called by muse, mutect2
- MCMDC2 | c.1306T>C p.Y436H | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV58035855; called by muse, mutect2, varscan2
- MEF2D | c.1225C>A p.P409T | Missense Mutation (SNP) | VAF 29/454 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.05); catalogued as COSV100560022; called by muse, mutect2
- MEIG1 | c.96T>A p.Y32* | Nonsense Mutation (SNP) | VAF 19/133 reads (14%) | catalogued as COSV65542957; called by muse, mutect2, varscan2
- MIP | c.229G>T p.V77L | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as COSV57513700; called by muse, mutect2, varscan2
- MMP16 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54193418; called by muse, mutect2, varscan2
- NALCN | c.3706C>A p.P1236T | Missense Mutation (SNP) | VAF 91/136 reads (67%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV51970562; called by muse, mutect2, varscan2
- NPR2 | c.2048-1G>C p.X683_splice | Splice Site (SNP) | VAF 33/138 reads (24%) | catalogued as COSV61043194; called by muse, mutect2, varscan2
- OR10H2 | c.845T>A p.L282H | Missense Mutation (SNP) | VAF 189/386 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100008759; called by muse, mutect2, varscan2
- OR14J1 | c.941G>A p.C314Y | Missense Mutation (SNP) | VAF 101/367 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV65846028; called by muse, mutect2, varscan2
- OR2V2 | c.419G>T p.R140M | Missense Mutation (SNP) | VAF 70/330 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as rs760468337, COSV100080094; called by muse, mutect2, varscan2
- PAX2 | c.922T>A p.S308T (on ENST00000428433 / NM_003987.5; = p.S285T on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.454); catalogued as COSV100695164; called by muse, mutect2, varscan2
- PAX2 | c.923C>T p.S308F (on ENST00000428433 / NM_003987.5; = p.S285F on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV100695165; called by muse, mutect2, varscan2
- POGK | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); catalogued as COSV63312586; called by muse, mutect2, varscan2
- RAD23A | c.511A>T p.M171L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV100330661; called by muse, mutect2, varscan2
- REL | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54365669, COSV54367957; called by muse, mutect2, varscan2
- RP1L1 | c.7105G>T p.G2369C | Missense Mutation (SNP) | VAF 63/173 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as rs758336283, COSV66757984; called by muse, mutect2, varscan2
- RPGRIP1 | c.121A>G p.M41V | Missense Mutation (SNP) | VAF 56/198 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.13); catalogued as COSV52858939; called by muse, mutect2, varscan2
- RPP40 | c.501G>A p.W167* | Nonsense Mutation (SNP) | VAF 18/32 reads (56%) | catalogued as COSV60292808; called by muse, mutect2, varscan2
- SCAMP3 | c.985C>T p.R329* | Nonsense Mutation (SNP) | VAF 17/92 reads (18%) | catalogued as rs930280834, COSV56947848; called by muse, mutect2, varscan2
- SEC62 | c.70G>C p.V24L | Missense Mutation (SNP) | VAF 27/215 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.038); catalogued as COSV61262409; called by muse, mutect2, varscan2
- SETD5 | c.3574G>T p.A1192S | Missense Mutation (SNP) | VAF 287/378 reads (76%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as COSV100200545; called by muse, mutect2, varscan2
- SHE | c.381G>T p.E127D | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV59071227; called by muse, varscan2
- SKA1 | c.572G>A p.R191K | Missense Mutation (SNP) | VAF 64/163 reads (39%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.908); catalogued as COSV53279959; called by muse, mutect2, varscan2
- SLC26A3 | c.1595C>A p.P532Q | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV60643262; called by muse, mutect2, varscan2
- SPAST | c.1298T>G p.L433R | Missense Mutation (SNP) | VAF 109/375 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV100188503; called by muse, mutect2, varscan2
- THPO | c.1004T>C p.L335P (on ENST00000649095 / NM_001290003.1; = p.L195P on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/102 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52617658; called by muse, mutect2, varscan2
- TMEM207 | c.44C>A p.T15K | Missense Mutation (SNP) | VAF 183/264 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV100718963; called by muse, mutect2, varscan2
- TRIM43 | c.621G>C p.E207D | Missense Mutation (SNP) | VAF 28/123 reads (23%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV55527758, COSV55529867; called by muse, mutect2, varscan2
- TRIP12 | c.2888G>A p.G963E | Missense Mutation (SNP) | VAF 29/57 reads (51%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as rs780632356, COSV99390107; called by muse, mutect2, varscan2
- TRPV3 | c.1801T>G p.F601V | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56796563; called by muse, mutect2, varscan2
- UCK2 | c.586T>C p.F196L | Missense Mutation (SNP) | VAF 63/321 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.774); catalogued as COSV63317120; called by muse, mutect2, varscan2
- WDFY3 | c.4620G>T p.M1540I | Missense Mutation (SNP) | VAF 11/223 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as COSV99883350; called by muse, mutect2
- ZNF425 | c.944G>A p.C315Y | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV65202954; called by muse, mutect2, varscan2
- ZNF536 | c.1819T>A p.F607I | Missense Mutation (SNP) | VAF 27/61 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.057); catalogued as COSV62836238; called by muse, mutect2, varscan2
- ECM1 | c.515del p.P172Lfs*6 | Frame Shift Del (DEL) | VAF 203/543 reads (37%) | called by mutect2, pindel, varscan2
- MLLT6 | c.1167dup p.K390Qfs*3 | Frame Shift Ins (INS) | VAF 5/40 reads (13%) | called by pindel, varscan2
- ZNF222 | c.6_15+10del p.X2_splice | Splice Site (DEL) | VAF 20/215 reads (9%) | called by mutect2, pindel
- ZNF222 | c.909_918delinsGAATG p.H303Qfs*10 | Frame Shift Del (DEL) | VAF 89/317 reads (28%) | called by pindel, varscan2*
- ADH1C | c.43C>T p.L15= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as rs1418359077, COSV72463729; called by muse, mutect2, varscan2
- AFF2 | c.3150T>C p.L1050= | Silent (SNP) | VAF 418/578 reads (72%) | catalogued as COSV54010849; called by muse, mutect2, varscan2
- AHNAK | c.6393C>G p.V2131= | Silent (SNP) | VAF 141/581 reads (24%) | catalogued as COSV57234481; called by muse, mutect2, varscan2
- BACE2 | c.636G>A p.E212= | Silent (SNP) | VAF 70/149 reads (47%) | catalogued as COSV100160771; called by muse, mutect2, varscan2
- BMPER | c.2040C>A p.V680= | Silent (SNP) | VAF 14/94 reads (15%) | catalogued as COSV51833589; called by muse, varscan2
- CARS1 | c.1500A>T p.A500= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as COSV53462197; called by muse, mutect2, varscan2
- DDX50 | c.1581C>T p.S527= | Silent (SNP) | VAF 29/127 reads (23%) | catalogued as COSV65292376, COSV65293516; called by muse, mutect2, varscan2
- FCGBP | c.10488C>T p.D3496= | Silent (SNP) | VAF 14/27 reads (52%) | catalogued as rs771508776; called by muse, mutect2, varscan2
- HFM1 | c.3033A>G p.L1011= | Silent (SNP) | VAF 58/121 reads (48%) | catalogued as rs138444412; called by muse, mutect2, varscan2
- HIVEP1 | c.7035A>C p.A2345= | Silent (SNP) | VAF 132/447 reads (30%) | catalogued as COSV65105689; called by muse, mutect2, varscan2
- KATNIP | c.4560G>T p.V1520= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV55193793; called by muse, mutect2, varscan2
- NRXN1 | c.3570G>A p.K1190= | Silent (SNP) | VAF 34/113 reads (30%) | catalogued as COSV60525191; called by muse, mutect2, varscan2
- PLA2G4C | c.369C>A p.T123= | Silent (SNP) | VAF 59/172 reads (34%) | catalogued as COSV62788478; called by muse, mutect2, varscan2
- PLEKHG2 | c.3771G>C p.T1257= | Silent (SNP) | VAF 47/240 reads (20%) | catalogued as COSV99217345; called by muse, mutect2, varscan2
- PTPRN2 | c.651G>C p.L217= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV101234319; called by muse, mutect2, varscan2
- RGL4 | c.1317G>A p.R439= | Silent (SNP) | VAF 19/25 reads (76%) | catalogued as COSV99318731; called by muse, mutect2, varscan2
- SCN2A | c.1356G>A p.Q452= | Silent (SNP) | VAF 44/88 reads (50%) | catalogued as COSV51858003; called by muse, mutect2, varscan2
- SLC11A1 | c.1494C>A p.G498= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as COSV51916774, COSV51920208; called by muse, mutect2, varscan2
- SLC24A4 | c.1434C>T p.I478= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1267653899, COSV54122873; called by muse, mutect2, varscan2
- SORL1 | c.5571A>T p.A1857= | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as COSV99493677; called by muse, mutect2, varscan2
- TRIM27 | c.1473C>T p.P491= | Silent (SNP) | VAF 84/319 reads (26%) | catalogued as COSV101019317; called by muse, mutect2, varscan2
- VPS33B | c.1197C>G p.L399= | Silent (SNP) | VAF 33/105 reads (31%) | catalogued as COSV60982060; called by muse, mutect2, varscan2
- XIRP2 | c.6351A>G p.P2117= (on ENST00000628543; = p.P2292= on NM_152381.6) | Silent (SNP) | VAF 124/486 reads (26%) | catalogued as COSV54739868; called by muse, mutect2, varscan2
- ZBTB16 | c.219C>T p.D73= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as COSV100251407; called by muse, mutect2, varscan2
- ZBTB38 | c.1305T>G p.G435= | Silent (SNP) | VAF 36/179 reads (20%) | catalogued as COSV100375585; called by muse, mutect2, varscan2
- ZNF677 | c.327G>A p.L109= | Silent (SNP) | VAF 92/224 reads (41%) | catalogued as COSV100447894; called by muse, mutect2, varscan2
- ZNF7 | c.156G>A p.E52= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as COSV57385699; called by muse, mutect2, varscan2
- CABYR | c.*17-235A>G | Intron (SNP) | VAF 14/114 reads (12%) | catalogued as COSV100111666; called by muse, mutect2, varscan2
- PRELID2 | c.*1A>G | 3'UTR (SNP) | VAF 14/75 reads (19%) | catalogued as COSV100597108; called by muse, mutect2, varscan2
- TMEM130 | c.*1G>A | 3'UTR (SNP) | VAF 23/79 reads (29%) | catalogued as COSV100228716; called by muse, mutect2, varscan2
